Somatic mutation profile of tumor specimen BA3117D (aliquot aq-BA3117D) from BEATAML1.0 case 2629, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated CEBPA; Tissue or organ of origin: Bone marrow; Age at diagnosis: 35.6 years (12,995 days).
Specimen BA3117D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05c366a1-db02-40c8-ab28-842fd0bb9d8e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3092D (Solid Tissue Normal), aliquot aq-BA3092D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3e8e086-8e65-44b6-b5f3-fea7ae5136a0

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.332_339del p.A111Gfs*56 | Frame Shift Del (DEL) | VAF 18/38 reads (47%) | catalogued as rs1555742213; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RUNX1 | c.416G>A p.R139Q (on ENST00000344691 / NM_001001890.3; = p.R166Q on NM_001754.5) | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1060499616, CM992139, COSV55866502, COSV55867644, COSV55875824; ClinVar: pathogenic; called by muse, mutect2
- FBXO11 | c.1919A>G p.Q640R (on ENST00000403359 / NM_001190274.2; = p.Q556R on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- PCNT | c.1325A>G p.E442G | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TP73 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.295); called by muse, mutect2, varscan2
